Somatic mutation profile of tumor specimen TCGA-AF-2689-01A (aliquot TCGA-AF-2689-01A-01D-1989-10) from TCGA case TCGA-AF-2689, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.3 years (15,082 days).
Specimen TCGA-AF-2689-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 903c1b7b-1f4d-4a7b-8920-8104e9f1de66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-2689-10A (Blood Derived Normal), aliquot TCGA-AF-2689-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e9695aa-6606-4978-92d9-afd878afc003

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 2, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APLP1 | c.340A>C p.I114L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99383528; called by muse, mutect2, varscan2
- BRD3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV57702071; called by muse, mutect2, varscan2
- BRF1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364184603, COSV100526795; called by muse, mutect2, varscan2
- COL27A1 | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs748351189, COSV100621524; called by muse, varscan2
- COL7A1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1189942401, COSV60393382; called by muse, mutect2, varscan2
- EEF1A2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99035645; called by muse, mutect2, varscan2
- GRIN2A | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199942034, COSV58035084, COSV58053195; called by muse, mutect2, varscan2
- IL21R | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as rs149097843; called by muse, mutect2, varscan2
- LONP1 | c.870+2T>G p.X290_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100638512; called by muse, varscan2
- MAGI2 | c.3757G>A p.E1253K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1240519716, COSV62648071, COSV62690145; called by muse, mutect2, varscan2
- MMP11 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV99303038; called by muse, mutect2, varscan2
- PRTG | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs775261213, COSV66838455; called by muse, mutect2, varscan2
- RADIL | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs375557900; called by muse, mutect2, varscan2
- RBBP8NL | c.1778C>G p.T593R | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53349096; called by muse, mutect2, varscan2
- RBM10 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100237880; called by muse, mutect2, varscan2
- THOC2 | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as CM158110; called by muse, mutect2, varscan2
- USP20 | c.1277-1G>A p.X426_splice | Splice Site (SNP) | VAF 40/89 reads (45%) | catalogued as COSV100204003; called by muse, mutect2, varscan2
- ADGRE2 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 90/106 reads (85%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, varscan2
- EPHB6 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- FRS2 | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- LZTR1 | c.179G>C p.C60S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NYAP1 | c.523T>C p.S175P | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDH19 | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ROBO2 | c.2350A>T p.T784S | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SPINK5 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZC3H15 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2
- EEF1A2 | c.948G>A p.S316= | Silent (SNP) | VAF 103/194 reads (53%) | catalogued as rs750037526, COSV53204690; called by muse, mutect2, varscan2
- HERC2 | c.14154T>G p.L4718= | Silent (SNP) | VAF 58/101 reads (57%) | called by muse, mutect2, varscan2
- ITGAX | c.414C>T p.L138= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51642481; called by muse, mutect2
- KIAA1522 | c.1749C>T p.P583= (on ENST00000373480 / NM_001198972.2; = p.P642= on NM_020888.3) | Silent (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- MROH7 | c.1647C>A p.A549= | Silent (SNP) | VAF 91/179 reads (51%) | catalogued as rs755872203; called by muse, mutect2, varscan2
- PARD6G | c.726C>T p.N242= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- PCDH19 | c.1698A>G p.P566= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- SIN3B | c.747C>T p.C249= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs760000692; called by muse, mutect2, varscan2
- UBXN11 | c.24T>A p.L8= | Silent (SNP) | VAF 60/302 reads (20%) | called by muse, mutect2, varscan2
- ZBTB46 | c.1647C>T p.G549= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as rs756424419, COSV55512071; called by muse, varscan2
- ATP2B1 | c.3351+514T>A | Intron (SNP) | VAF 81/329 reads (25%) | called by muse, mutect2, varscan2
